Somatic mutation profile of tumor specimen TCGA-VN-A88P-01A (aliquot TCGA-VN-A88P-01A-11D-A34U-08) from TCGA case TCGA-VN-A88P, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.0 years (21,916 days).
Specimen TCGA-VN-A88P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5c43bb9-f845-485e-b7cd-3d2df874d374.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VN-A88P-10A (Blood Derived Normal), aliquot TCGA-VN-A88P-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cff26f7-cd58-4a50-a0c3-d8bc5b7dcc90

The open-access MAF lists 43 somatic variants for this specimen: 31 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Frame Shift Del 3, Nonsense Mutation 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.4379del p.P1460Hfs*46 | Frame Shift Del (DEL) | VAF 44/141 reads (31%) | catalogued as rs1240601136; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CNTNAP5 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV101443119; called by muse, mutect2, varscan2
- DHX33 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.279); catalogued as rs373067235; called by muse, mutect2, varscan2
- DNAH10 | c.3190G>A p.D1064N (on ENST00000409039; = p.D1003N on NM_207437.3) | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.315); catalogued as COSV101292022; called by muse, mutect2, varscan2
- FAM71B | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV100261863; called by muse, mutect2, varscan2
- FNDC8 | c.29del p.G10Efs*8 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs1486878443; called by mutect2, varscan2
- IL10 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs374619208; called by muse, mutect2, varscan2
- IPPK | c.1337A>G p.E446G | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99845415; called by muse, mutect2, varscan2
- ITPR2 | c.5420T>A p.F1807Y | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101189839; called by muse, mutect2
- JCAD | c.4071G>C p.E1357D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100948125; called by muse, mutect2, varscan2
- NT5E | c.848T>G p.F283C | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100003917; called by muse, mutect2, varscan2
- NUP210 | c.3239C>T p.P1080L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1298359918, COSV54410771, COSV99595643; called by muse, mutect2, varscan2
- PDZRN3 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs144715916; called by muse, mutect2, varscan2
- PHYHIP | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.949); catalogued as rs1281604388, COSV100394994; called by muse, mutect2, varscan2
- PIWIL1 | c.1344C>A p.N448K | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99806048; called by muse, mutect2, varscan2
- PLEKHH2 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.181); catalogued as COSV99174371, COSV99174571; called by muse, mutect2, varscan2
- PPP2R2B | c.157C>T p.R53* (on ENST00000394409; = p.R119* on NM_181674.2) | Nonsense Mutation (SNP) | VAF 102/440 reads (23%) | catalogued as COSV60780781; called by muse, varscan2
- PTK7 | c.2264A>G p.Q755R | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV100029885; called by muse, mutect2, varscan2
- RANBP6 | c.2248C>T p.L750F | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV52391809; called by muse, mutect2, varscan2
- RANBP6 | c.2247T>A p.Y749* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | catalogued as rs765830429, COSV99424004; called by muse, mutect2, varscan2
- RAPGEF4 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99909887, COSV99910871; called by muse, varscan2
- RNF214 | c.1147T>C p.S383P | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as COSV100326506; called by muse, mutect2, varscan2
- RNMT | c.1404G>C p.L468F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV100054477, COSV51093326; called by muse, mutect2, varscan2
- SERPINB8 | c.669G>C p.E223D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV54639668; called by muse, mutect2, varscan2
- SORBS1 | c.3842C>G p.T1281S (on ENST00000361941 / NM_001034954.2; = p.T673S on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99527501; called by muse, mutect2, varscan2
- UNC79 | c.1033T>A p.C345S (on ENST00000393151 / NM_001346218.2; = p.C168S on NM_020818.5) | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99826079; called by muse, mutect2, varscan2
- VAV3 | c.293A>T p.D98V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1405207669, COSV100894248; called by muse, mutect2, varscan2
- ZBTB20 | c.1286G>T p.G429V (on ENST00000474710 / NM_001164342.2; = p.G356V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs532683480, COSV100612859; called by muse, mutect2, varscan2
- ZBTB7A | c.1020G>T p.E340D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100475388, COSV59326830; called by muse, mutect2, varscan2
- CD37 | c.606_608del p.S202del | In Frame Del (DEL) | VAF 18/66 reads (27%) | called by pindel, varscan2
- PI15 | c.774_777del p.*259Ffs*40 | Frame Shift Del (DEL) | VAF 37/73 reads (51%) | called by mutect2, pindel, varscan2
- AMER3 | c.612G>T p.P204= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100366045; called by muse, mutect2, varscan2
- ANGPTL2 | c.423C>A p.L141= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV52232795, COSV99400987; called by muse, mutect2, varscan2
- BRINP1 | c.1275C>T p.P425= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99774603; called by muse, mutect2, varscan2
- COL4A2 | c.1878C>T p.P626= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs763465240, COSV100847360, COSV64632134; called by mutect2, varscan2
- PCDHA4 | c.1812C>T p.N604= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs17844283, COSV100793184; called by muse, mutect2, varscan2
- SDK1 | c.3249T>G p.P1083= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as COSV101268831; called by muse, mutect2, varscan2
- SLC26A11 | c.1386C>T p.L462= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1348130452, COSV100755295; called by muse, mutect2, varscan2
- TMEM74 | c.729C>T p.G243= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV52463872; called by muse, mutect2, varscan2
- TMF1 | c.2064T>G p.R688= | Silent (SNP) | VAF 56/125 reads (45%) | catalogued as COSV101275404; called by muse, mutect2, varscan2
- UNC13C | c.5913G>A p.T1971= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs771255788, COSV52906477; called by muse, mutect2, varscan2
- ZNF518B | c.666C>G p.V222= | Silent (SNP) | VAF 10/300 reads (3%) | catalogued as COSV100456566; called by muse, mutect2
- PRRX1 | c.599+3922G>A | Intron (SNP) | VAF 21/146 reads (14%) | catalogued as rs148536447; called by muse, mutect2, varscan2
